Somatic mutation profile of tumor specimen TCGA-DD-AAE1-01A (aliquot TCGA-DD-AAE1-01A-11D-A40R-10) from TCGA case TCGA-DD-AAE1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 52.2 years (19,073 days).
Specimen TCGA-DD-AAE1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 399a50f4-3246-4e88-a136-7424571bc388.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAE1-10A (Blood Derived Normal), aliquot TCGA-DD-AAE1-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/782b9bd8-2005-45cb-8c02-82d111d48150

The open-access MAF lists 53 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 29, Silent 12, Nonsense Mutation 4, In Frame Del 3, Splice Site 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV99329253; called by muse, mutect2, varscan2
- ACACB | c.1403A>T p.E468V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV100623182; called by muse, mutect2, varscan2
- AOX1 | c.3419G>C p.G1140A | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99613757; called by muse, mutect2, varscan2
- AP3B1 | c.1041G>T p.R347S | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.348); catalogued as COSV99672208; called by muse, mutect2, varscan2
- ARHGAP5 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as COSV100565636; called by muse, mutect2, varscan2
- AXIN1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 20/28 reads (71%) | catalogued as COSV51993729; called by muse, mutect2, varscan2
- BCL11A | c.2231C>T p.A744V (on ENST00000335712 / NM_001365609.1; = p.A778V on NM_022893.4) | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100186279; called by muse, mutect2, varscan2
- BPIFA2 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV99487986; called by muse, mutect2, varscan2
- CA11 | c.567+1G>A p.X189_splice | Splice Site (SNP) | VAF 44/105 reads (42%) | catalogued as COSV50032698; called by muse, mutect2
- CACNA1S | c.4264G>A p.V1422M | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224786667, COSV100755248; called by muse, mutect2, varscan2
- CFHR4 | c.1067A>T p.N356I (on ENST00000367416 / NM_001201551.2; = p.N110I on NM_006684.5) | Missense Mutation (SNP) | VAF 187/1048 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99261193; called by muse, mutect2, varscan2
- CTNND2 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV100479885; called by muse, mutect2, varscan2
- DCDC1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV60853334; called by muse, mutect2, varscan2
- DELE1 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99519971; called by muse, mutect2, varscan2
- EBNA1BP2 | c.66G>A p.E22= | Splice Region (SNP) | VAF 30/46 reads (65%) | catalogued as rs1168939428, COSV99356067; called by muse, mutect2, varscan2
- EML5 | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as COSV100716081; called by muse, mutect2, varscan2
- EOLA1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 274/314 reads (87%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs782813690, COSV63734180; called by muse, mutect2, varscan2
- KIRREL2 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99384300; called by muse, mutect2, varscan2
- KRT17 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs374932182; called by muse, mutect2, varscan2
- MBP | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100592859; called by muse, mutect2, varscan2
- OGDHL | c.1938G>T p.M646I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV65103328; called by muse, mutect2
- OLFML2B | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 101/156 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as rs771554171, COSV99668760; called by muse, mutect2, varscan2
- PARVB | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs201782671, COSV58688480, COSV99072296; called by muse, mutect2, varscan2
- PCCA | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887012; called by muse, mutect2, varscan2
- PCDHB12 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV99507644; called by muse, mutect2, varscan2
- PGA5 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211675538, COSV100409360; called by muse, mutect2, varscan2
- PTPRN | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99834229; called by muse, mutect2, varscan2
- RYR3 | c.7132A>G p.T2378A (on ENST00000389232; = p.T2379A on NM_001036.6) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV101213763; called by muse, mutect2, varscan2
- SDK2 | c.3682C>A p.R1228S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV101168269; called by muse, mutect2, varscan2
- TONSL | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101340296; called by muse, mutect2, varscan2
- VIT | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV101007679; called by muse, mutect2, varscan2
- WIZ | c.4048A>G p.K1350E (on ENST00000673675 / NM_001371589.1; = p.K255E on NM_021241.3) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.378); catalogued as rs779582177, COSV99653629; called by muse, mutect2, varscan2
- ZNF143 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV100217980; called by muse, mutect2, varscan2
- ZNF219 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV100070606; called by muse, mutect2, varscan2
- ZNF280B | c.1232G>T p.R411I | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100840415; called by muse, mutect2, varscan2
- A2M | c.3533-5_3540del p.X1178_splice | Splice Site (DEL) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- IRS1 | c.1461_1478del p.G488_R493del | In Frame Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- ITGB3 | c.1074_1078del p.L359Hfs*12 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | called by mutect2, pindel, varscan2
- KCTD20 | c.994_1006delinsC p.K332_G336delinsR | In Frame Del (DEL) | VAF 41/105 reads (39%) | called by pindel, varscan2*
- PAQR8 | c.588_602del p.A197_Y201del | In Frame Del (DEL) | VAF 32/87 reads (37%) | called by mutect2, pindel, varscan2
- WAPL | c.1202dup p.A402Gfs*7 | Frame Shift Ins (INS) | VAF 43/92 reads (47%) | called by mutect2, varscan2
- ACTL10 | c.690C>T p.A230= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV99865059; called by muse, mutect2, varscan2
- BICD2 | c.1506G>A p.L502= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100794242; called by muse, mutect2, varscan2
- CBLN2 | c.327C>T p.S109= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99504105, COSV99504561; called by muse, mutect2, varscan2
- HYLS1 | c.495A>G p.Q165= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV99700076; called by muse, mutect2, varscan2
- LAP3 | c.567A>T p.G189= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99884496; called by muse, mutect2, varscan2
- MC4R | c.249C>A p.I83= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100236095; called by muse, mutect2
- MINAR1 | c.2076A>G p.E692= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100549127; called by muse, varscan2
- PPP1R12C | c.1932T>C p.A644= | Silent (SNP) | VAF 101/216 reads (47%) | catalogued as COSV99136917; called by muse, mutect2, varscan2
- SLC38A10 | c.343C>T p.L115= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99917785; called by muse, mutect2, varscan2
- ZNF202 | c.447G>A p.T149= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs772780549, COSV60248640; called by muse, mutect2, varscan2
- ZNF329 | c.1582C>A p.R528= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV100798804; called by muse, mutect2, varscan2
- ZNF678 | c.1525A>C p.R509= | Silent (SNP) | VAF 76/381 reads (20%) | catalogued as COSV100652911; called by muse, mutect2, varscan2
